Somatic mutation profile of tumor specimen ALCH-ADTR-TTP1-A (aliquot ALCH-ADTR-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADTR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.0 years (26,307 days).
Specimen ALCH-ADTR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81737665-ddc2-4bcd-b03f-d9df00ee187c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADTR-NB1-A (Blood Derived Normal), aliquot ALCH-ADTR-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d096895-b3c1-4514-be16-18dc67086656

The open-access MAF lists 371 somatic variants for this specimen: 257 protein-altering or splice-affecting, 73 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 73, Intron 16, Frame Shift Del 11, Nonsense Mutation 11, RNA 9, Splice Site 8, 3'UTR 6, 5'UTR 5, 5'Flank 4, Splice Region 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 42/209 reads (20%) | catalogued as CM034508, COSV100796809; called by muse, mutect2, varscan2
- AP3B2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 25/379 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866031332, COSV99916989; called by muse, mutect2
- ARHGEF3 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs899889736; called by muse, mutect2
- BRCA2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 27/617 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555281067, COSV66456484; ClinVar: uncertain significance; called by muse, mutect2
- BRINP3 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 40/932 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100818667, COSV66514204; called by muse, mutect2
- BRINP3 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); catalogued as rs767672121, COSV100818411; called by muse, mutect2, varscan2
- CCDC66 | c.813A>G p.L271= (on ENST00000394672 / NM_001353147.1; = p.L237= on NM_001012506.5 and 6 other RefSeq transcripts) | Splice Region (SNP) | VAF 42/290 reads (14%) | catalogued as rs745404029; called by muse, varscan2
- CDH18 | c.169T>G p.W57G | Missense Mutation (SNP) | VAF 72/784 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936980; called by muse, mutect2
- COL15A1 | c.3032-1G>T p.X1011_splice | Splice Site (SNP) | VAF 64/648 reads (10%) | catalogued as COSV66641776; called by muse, mutect2
- COL22A1 | c.1633G>T p.G545C | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57356447; called by muse, varscan2
- CORIN | c.1103G>T p.C368F | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758154840, COSV56693205; called by muse, mutect2
- CSMD1 | c.2261G>T p.R754L (on ENST00000520002; = p.R753L on NM_033225.6) | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs748646070, COSV100148839, COSV59366434; called by muse, mutect2
- CSMD1 | c.1431C>A p.D477E (on ENST00000520002; = p.D476E on NM_033225.6) | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV101221025; called by muse, mutect2, varscan2
- CTAGE8 | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 40/1105 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1563090034; called by muse, mutect2
- CYLC1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as rs779454288, COSV61413564; called by muse, mutect2
- CYP1B1 | c.1019A>T p.Q340L | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.435); catalogued as COSV99572727; called by muse, mutect2, varscan2
- DPF3 | c.798G>T p.L266F | Missense Mutation (SNP) | VAF 42/475 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63499213; called by muse, mutect2
- ENGASE | c.1799G>T p.R600L | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.427); catalogued as COSV100285612; called by muse, mutect2, varscan2
- EPHA3 | c.447T>A p.D149E | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60709770; called by muse, mutect2, varscan2
- ETNPPL | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56595024, COSV99625068; called by muse, mutect2
- EXOC2 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1238432006; called by muse, mutect2, varscan2
- EXOC7 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV58740338; called by muse, mutect2
- EYS | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as rs1291012335; called by muse, mutect2
- FAP | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 36/465 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs373219307, COSV51859783; called by muse, mutect2
- FAT3 | c.8708C>G p.S2903C | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs774850320; called by muse, mutect2
- FBN2 | c.6466C>A p.P2156T | Missense Mutation (SNP) | VAF 66/710 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99326302; called by muse, mutect2
- FREM3 | c.4788C>A p.F1596L | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61681567; called by muse, mutect2, varscan2
- FSIP2 | c.4417G>T p.A1473S | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV58085506; called by muse, mutect2
- GALNT18 | c.1240A>T p.K414* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | catalogued as COSV57157586; called by muse, mutect2, varscan2
- HUWE1 | c.7808G>T p.R2603L | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53345431; called by muse, mutect2, varscan2
- IQCA1 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 64/569 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV54500617; called by muse, varscan2
- KEAP1 | c.998del p.G333Afs*67 | Frame Shift Del (DEL) | VAF 32/268 reads (12%) | catalogued as COSV99407360; called by mutect2, pindel, varscan2
- L1CAM | c.1433C>A p.A478D | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1298830102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 33/510 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV53280936; called by muse, mutect2
- LRRC53 | c.740A>T p.N247I | Missense Mutation (SNP) | VAF 97/558 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs758506545; called by muse, mutect2, varscan2
- MBNL1 | c.1009C>T p.P337S (on ENST00000282486 / NM_207293.2; = p.P319S on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99220766; called by muse, mutect2
- MUC16 | c.13307C>A p.P4436H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV67481968; called by muse, mutect2, varscan2
- MYOD1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs759489503, COSV51455935; called by muse, mutect2, varscan2
- NALCN | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51950117; called by muse, mutect2
- NCL | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 46/622 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV59548011; called by muse, mutect2
- NF1 | c.7490C>T p.P2497L (on ENST00000358273 / NM_001042492.3; = p.P2476L on NM_000267.3) | Missense Mutation (SNP) | VAF 80/835 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.293); catalogued as rs1555536347; ClinVar: uncertain significance; called by muse, mutect2
- NLGN3 | c.2251G>C p.G751R (on ENST00000358741 / NM_181303.2; = p.G731R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.07); catalogued as COSV62441538; called by muse, mutect2, varscan2
- OR11L1 | c.396C>G p.Y132* | Nonsense Mutation (SNP) | VAF 17/403 reads (4%) | catalogued as COSV100869508, COSV63315737; called by muse, mutect2
- OR4C5 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 71/885 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as rs771900513; called by muse, mutect2
- OR4K2 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV53848119; called by muse, mutect2
- OR5L1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 38/514 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1363294712, COSV61732870, COSV61733662; called by muse, mutect2
- OR5T1 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV57303483; called by muse, mutect2
- OXR1 | c.2527C>T p.H843Y (on ENST00000442977 / NM_001198532.1; = p.H815Y on NM_018002.3) | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935419992; called by muse, mutect2, varscan2
- P2RX6 | c.283T>C p.W95R | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375246049; called by muse, mutect2, varscan2
- PANK1 | c.1172C>T p.P391L (on ENST00000307534 / NM_148977.2; = p.P166L on NM_138316.4) | Missense Mutation (SNP) | VAF 68/666 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV56810784; called by muse, mutect2, varscan2
- PCDH15 | c.4188G>C p.L1396F | Missense Mutation (SNP) | VAF 60/994 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs1207583441; called by muse, mutect2
- PGM5 | c.1416C>A p.S472R | Missense Mutation (SNP) | VAF 37/526 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.116); catalogued as rs782063471; called by muse, mutect2
- PRB1 | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.829); catalogued as rs774541637; called by muse, mutect2, varscan2
- PRUNE2 | c.3991C>G p.Q1331E | Missense Mutation (SNP) | VAF 37/483 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100944319; called by muse, mutect2
- RASGRP4 | c.1904G>C p.C635S | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs751062755; called by muse, mutect2, varscan2
- REM2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 51/670 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs758270170; called by muse, mutect2
- RNASE13 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 58/477 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100409553; called by muse, mutect2, varscan2
- SLC17A6 | c.1558C>A p.H520N | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1379087293, COSV54133405, COSV99580661; called by muse, mutect2
- SLC25A47 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs764090629, COSV64162638; called by muse, mutect2
- SLCO6A1 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101135200, COSV65805396; called by muse, mutect2, varscan2
- SPATC1 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV66300647; called by muse, mutect2, varscan2
- SPDL1 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 60/590 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs143182474, COSV54669985; called by muse, mutect2, varscan2
- SPON1 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as rs145404118; called by muse, mutect2
- SSTR5 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142539751, COSV53511336; called by muse, mutect2
- STXBP5L | c.412T>C p.W138R | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1376773241; called by muse, mutect2, varscan2
- SYN3 | c.1624del p.L542* | Frame Shift Del (DEL) | VAF 47/271 reads (17%) | catalogued as COSV100249483; called by mutect2, pindel, varscan2
- TANC2 | c.4858C>G p.P1620A | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV67334294; called by muse, mutect2
- TKTL2 | c.659A>G p.H220R | Missense Mutation (SNP) | VAF 52/568 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as rs368537868; called by muse, mutect2
- TMEM151A | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV59172990; called by muse, mutect2, varscan2
- TPM2 | c.640-2del p.X214_splice | Splice Site (DEL) | VAF 111/833 reads (13%) | catalogued as COSV61404796, COSV61404923; called by mutect2, pindel, varscan2
- TTN | c.22975G>A p.V7659I (on ENST00000591111; = p.V6732I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/129 reads (12%) | PolyPhen possibly damaging (0.502); catalogued as rs200395305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTRN | c.7037A>T p.E2346V | Missense Mutation (SNP) | VAF 56/986 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs753239973; called by muse, mutect2
- VENTX | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769411210; called by muse, mutect2
- XRN1 | c.4768A>G p.M1590V | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs765244021; called by muse, mutect2
- ZFP30 | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 42/684 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.278); catalogued as COSV63622380; called by muse, mutect2
- ZGPAT | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 31/132 reads (23%) | catalogued as rs758275876; called by muse, mutect2, varscan2
- ZNF479 | c.1393T>C p.Y465H | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58641269; called by muse, mutect2
- AC090517.4 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS2 | c.3175T>A p.S1059T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- AEBP2 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AMER2 | c.1136C>A p.T379K | Missense Mutation (SNP) | VAF 25/505 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ANO3 | c.315C>T p.A105= | Splice Region (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2, varscan2
- ASH1L | c.4371G>T p.R1457S | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- BIN1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 60/626 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2
- BUB1B | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 62/906 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C12orf42 | c.586A>C p.T196P | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.214); called by muse, mutect2
- C14orf39 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2
- C5orf51 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 187/796 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CACNA2D1 | c.3003-2A>T p.X1001_splice (on ENST00000356253 / NM_001366867.1; = p.X989_splice on NM_000722.4) | Splice Site (SNP) | VAF 44/512 reads (9%) | called by muse, mutect2
- CACNA2D4 | c.1424G>C p.R475P | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CALCR | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC114 | c.748del p.E250Rfs*22 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by mutect2, pindel
- CDH9 | c.2120G>A p.W707* | Nonsense Mutation (SNP) | VAF 177/645 reads (27%) | called by muse, mutect2, varscan2
- CINP | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CIT | c.2419G>T p.E807* | Nonsense Mutation (SNP) | VAF 35/341 reads (10%) | called by muse, mutect2, varscan2
- CKAP5 | c.1651_1652del p.A551Wfs*29 | Frame Shift Del (DEL) | VAF 36/305 reads (12%) | called by mutect2, pindel, varscan2
- CNBD2 | c.1106C>G p.T369S | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL6A3 | c.7092+1G>T p.X2364_splice | Splice Site (SNP) | VAF 123/755 reads (16%) | called by muse, mutect2, varscan2
- COPS8 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 35/449 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2
- CPE | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.046); called by muse, mutect2
- CPNE9 | c.1196T>A p.L399H | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB1 | c.3151dup p.W1051Lfs*27 | Frame Shift Ins (INS) | VAF 151/1169 reads (13%) | called by mutect2, pindel, varscan2
- CROT | c.512T>G p.I171S | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CUZD1 | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CYP2C8 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 84/872 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- CYTIP | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2
- DALRD3 | c.607A>G p.N203D (on ENST00000341949 / NM_001009996.3; = p.N36D on NM_018114.5) | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- DCAF16 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); called by muse, varscan2
- DCAF8L2 | c.642T>A p.F214L | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- DCHS1 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.112); called by muse, mutect2
- DMD | c.5436C>A p.F1812L | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- DRD3 | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DROSHA | c.1037C>A p.P346Q | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.022); called by muse, mutect2
- DZIP3 | c.2972G>T p.G991V | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- E2F7 | c.2194G>T p.G732C | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- EARS2 | c.634A>T p.S212C | Missense Mutation (SNP) | VAF 60/619 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2
- ENOX2 | c.641G>T p.W214L (on ENST00000338144 / NM_001382520.1; = p.W185L on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- EPHA4 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 51/563 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHA6 | c.2704A>T p.S902C (on ENST00000389672 / NM_001080448.3; = p.S294C on NM_173655.4) | Missense Mutation (SNP) | VAF 42/670 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- FA2H | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2
- FAM160A2 | c.2361G>A p.M787I (on ENST00000449352 / NM_001098794.2; = p.M801I on NM_032127.4) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- FBN2 | c.6467C>A p.P2156Q | Missense Mutation (SNP) | VAF 68/714 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- FBXO43 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FYB2 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- FZD1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- GALC | c.1886G>C p.W629S | Missense Mutation (SNP) | VAF 52/660 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GASK1A | c.1318_1330del p.C440Lfs*53 | Frame Shift Del (DEL) | VAF 20/178 reads (11%) | called by mutect2, pindel
- GDAP1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 90/958 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- GDPD1 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1349A>C p.E450A | Missense Mutation (SNP) | VAF 44/888 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- GTF3C2 | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.084); called by muse, mutect2
- HKDC1 | c.716T>A p.M239K | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HKDC1 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- HOXC9 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- HTR5A | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HYAL3 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGSF9B | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- IMP4 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- IQCA1 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- IRF8 | c.1215G>T p.M405I | Missense Mutation (SNP) | VAF 80/1040 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ITPRID1 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 24/500 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.268); called by muse, mutect2
- KCNH1 | c.1966C>A p.Q656K (on ENST00000271751 / NM_172362.3; = p.Q629K on NM_002238.4) | Missense Mutation (SNP) | VAF 29/504 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2
- KCNK10 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIF20B | c.3144del p.N1048Kfs*21 (on ENST00000371728 / NM_001284259.2; = p.N1008Kfs*21 on NM_016195.4) | Frame Shift Del (DEL) | VAF 46/438 reads (11%) | called by mutect2, varscan2
- KIR2DL3 | c.370+1G>T p.X124_splice | Splice Site (SNP) | VAF 97/577 reads (17%) | called by muse, mutect2, varscan2
- LACC1 | c.71T>C p.L24S | Missense Mutation (SNP) | VAF 29/435 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- LCE2D | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 76/359 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LDLRAD3 | c.193+1G>T p.X65_splice | Splice Site (SNP) | VAF 43/496 reads (9%) | called by muse, mutect2
- LOXHD1 | c.5844C>A p.H1948Q (on ENST00000642948; = p.H1886Q on NM_144612.7) | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.583); called by muse, mutect2
- LPAR5 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.11434T>A p.C3812S | Missense Mutation (SNP) | VAF 39/387 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- LUZP2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- MAGEB3 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MAGEB6B | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAGEC1 | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- MARCHF9 | c.266dup p.A91Rfs*10 | Frame Shift Ins (INS) | VAF 13/134 reads (10%) | called by mutect2, pindel, varscan2
- MB21D2 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2
- MDGA2 | c.2350G>C p.V784L (on ENST00000399232 / NM_001113498.2; = p.V486L on NM_182830.4) | Missense Mutation (SNP) | VAF 22/503 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2
- METTL18 | c.508del p.E170Nfs*15 | Frame Shift Del (DEL) | VAF 96/740 reads (13%) | called by mutect2, pindel, varscan2
- MGAT3 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP20 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 60/856 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MMS22L | c.1979G>T p.C660F | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTA3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 23/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC19 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2
- MUC5B | c.6029C>G p.P2010R | Missense Mutation (SNP) | VAF 78/866 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- MYH4 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 48/598 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); called by muse, mutect2
- MYH9 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 137/770 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MYO18B | c.5089G>T p.A1697S | Missense Mutation (SNP) | VAF 85/552 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- MYPN | c.2225C>A p.S742Y | Missense Mutation (SNP) | VAF 133/1488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NCAPG2 | c.1932A>T p.K644N | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2
- NCKAP5 | c.1007G>T p.S336I | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NHSL2 | c.1184T>C p.M395T (on ENST00000510661; = p.M761T on NM_001013627.2) | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NIBAN1 | c.2760T>A p.S920R | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2
- NLGN3 | c.2252G>T p.G751V (on ENST00000358741 / NM_181303.2; = p.G731V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP8 | c.2992A>G p.I998V | Missense Mutation (SNP) | VAF 82/507 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NLRX1 | c.24del p.R9Gfs*22 | Frame Shift Del (DEL) | VAF 30/342 reads (9%) | called by mutect2, pindel
- NOS2 | c.532A>T p.T178S | Missense Mutation (SNP) | VAF 33/391 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2
- NRCAM | c.3647A>T p.K1216M (on ENST00000379028 / NM_001371124.1; = p.K1095M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/521 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2AJ1 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 26/596 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR2T11 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 122/644 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR2T12 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 116/849 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4A16 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 41/702 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.044); called by muse, mutect2
- OR6C3 | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- OTOG | c.5404C>A p.L1802I | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OTOG | c.7776G>T p.E2592D | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- P2RX5 | c.168_170del p.Q56_D57delinsH | In Frame Del (DEL) | VAF 59/471 reads (13%) | called by mutect2, pindel, varscan2
- PAX7 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH10 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCDHB7 | c.2111T>A p.L704H | Missense Mutation (SNP) | VAF 97/1597 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- PCDHB8 | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 102/2294 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2
- PELI1 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- PGR | c.1854C>A p.N618K | Missense Mutation (SNP) | VAF 46/628 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHF2 | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2
- PHF21B | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PKD1 | c.5167G>T p.V1723L | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEC | c.8094G>C p.E2698D (on ENST00000322810 / NM_201380.4; = p.E2588D on NM_000445.5) | Missense Mutation (SNP) | VAF 80/874 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.534); called by muse, mutect2
- POGLUT2 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- POGLUT3 | c.669A>T p.L223F | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POLR2H | c.156G>A p.L52= | Splice Region (SNP) | VAF 41/348 reads (12%) | called by muse, mutect2, varscan2
- POMT2 | c.620del p.M207Sfs*2 | Frame Shift Del (DEL) | VAF 98/995 reads (10%) | called by mutect2, pindel, varscan2
- PPP1R2B | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 74/787 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- PRMT3 | c.200G>C p.C67S | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRRG2 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PSG5 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 68/530 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PSG7 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 72/494 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PTPRZ1 | c.1180A>G p.N394D | Missense Mutation (SNP) | VAF 46/459 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RADIL | c.1797G>T p.W599C | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2
- RASA2 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- RGPD4 | c.5217G>T p.M1739I | Missense Mutation (SNP) | VAF 62/1222 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2
- RTF1 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 41/461 reads (9%) | called by muse, mutect2
- RYR2 | c.4501A>C p.N1501H | Missense Mutation (SNP) | VAF 125/759 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RYR2 | c.4901del p.E1634Gfs*9 | Frame Shift Del (DEL) | VAF 36/286 reads (13%) | called by mutect2, pindel
- S100B | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 68/577 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL1 | c.2103G>T p.K701N | Missense Mutation (SNP) | VAF 37/433 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- SHLD2 | c.464A>C p.Q155P | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SHOX | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 29/331 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2
- SLC1A4 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC38A8 | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- SLC46A2 | c.1045A>T p.T349S | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.653); called by muse, mutect2
- SLCO1B1 | c.760T>A p.W254R | Missense Mutation (SNP) | VAF 82/568 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOWAHB | c.2233A>T p.R745* | Nonsense Mutation (SNP) | VAF 35/333 reads (11%) | called by muse, mutect2, varscan2
- SPPL2C | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2252G>T p.R751I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- TANC2 | c.4857C>G p.S1619R | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); called by muse, mutect2
- TAP1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 227/1356 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, varscan2
- TAP1 | c.495G>T p.L165F | Missense Mutation (SNP) | VAF 226/1353 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, varscan2
- TCEAL2 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCERG1 | c.1560G>T p.K520N | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TECPR2 | c.4052A>C p.K1351T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TESPA1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2
- TEX49 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 31/379 reads (8%) | called by muse, mutect2
- TNR | c.2018A>T p.Q673L | Missense Mutation (SNP) | VAF 105/652 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM49 | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 78/1238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPM1 | c.1898A>T p.Q633L | Missense Mutation (SNP) | VAF 77/921 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- TRPM1 | c.1197+2T>C p.X399_splice | Splice Site (SNP) | VAF 70/1008 reads (7%) | called by muse, mutect2
- TTN | c.94652C>A p.A31551E (on ENST00000591111; = p.A24127E on NM_003319.4) | Missense Mutation (SNP) | VAF 18/277 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.29032C>A p.L9678I (on ENST00000591111; = p.L8751I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TXLNB | c.1210A>T p.T404S | Missense Mutation (SNP) | VAF 27/602 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.406); called by muse, mutect2
- TXNDC11 | c.1071G>T p.W357C (on ENST00000356957 / NM_001303447.2; = p.W330C on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/712 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UGT3A2 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 227/821 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- UNC45A | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- URI1 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- WAC | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- WIPI2 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 59/638 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2
- XBP1 | c.197A>T p.H66L | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- XIRP2 | c.8140C>G p.P2714A (on ENST00000628543; = p.P2889A on NM_152381.6) | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2
- ZBTB16 | c.787A>T p.S263C | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ZFHX4 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ZFHX4 | c.2074T>A p.Y692N | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMIZ1 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF382 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 76/451 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF536 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF536 | c.1698C>A p.Y566* | Nonsense Mutation (SNP) | VAF 46/592 reads (8%) | called by muse, mutect2
- ZNF679 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZNF804A | c.1293del p.K431Nfs*39 | Frame Shift Del (DEL) | VAF 22/212 reads (10%) | called by pindel, varscan2*
- ZNF99 | c.577A>T p.R193* | Nonsense Mutation (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- ABCA12 | c.4321C>T p.L1441= (on ENST00000272895 / NM_173076.3; = p.L1123= on NM_015657.3) | Silent (SNP) | VAF 96/964 reads (10%) | called by muse, mutect2, varscan2
- ABCC12 | c.2313C>T p.S771= | Silent (SNP) | VAF 45/386 reads (12%) | catalogued as rs780695755, COSV60912069; called by muse, mutect2, varscan2
- ACVR2B | c.78A>C p.T26= | Silent (SNP) | VAF 43/418 reads (10%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.1587C>T p.A529= | Silent (SNP) | VAF 76/941 reads (8%) | catalogued as COSV51420550; called by muse, mutect2
- AGRN | c.1431G>C p.A477= | Silent (SNP) | VAF 71/371 reads (19%) | called by muse, mutect2, varscan2
- ALG2 | c.315C>T p.A105= | Silent (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- ALOX15B | c.1233C>T p.H411= | Silent (SNP) | VAF 56/377 reads (15%) | catalogued as rs752661884; called by muse, mutect2, varscan2
- ARFGEF2 | c.1554C>T p.V518= | Silent (SNP) | VAF 175/866 reads (20%) | called by muse, mutect2, varscan2
- ATP9A | c.3024C>T p.A1008= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs756237707; called by muse, mutect2, varscan2
- CCDC185 | c.957C>A p.R319= | Silent (SNP) | VAF 22/414 reads (5%) | called by muse, mutect2
- CNTN4 | c.2934A>T p.G978= | Silent (SNP) | VAF 63/708 reads (9%) | called by muse, mutect2
- COL19A1 | c.2931G>T p.G977= | Silent (SNP) | VAF 44/518 reads (8%) | catalogued as rs751012564; called by muse, mutect2
- COLGALT1 | c.315G>T p.L105= | Silent (SNP) | VAF 52/554 reads (9%) | called by muse, mutect2
- CPNE6 | c.210C>T p.V70= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- CREBBP | c.3723C>T p.F1241= | Silent (SNP) | VAF 97/1020 reads (10%) | catalogued as COSV52139808; called by muse, mutect2
- CRYBG3 | c.498G>T p.G166= | Silent (SNP) | VAF 60/792 reads (8%) | called by muse, mutect2
- CSMD3 | c.5319T>G p.V1773= (on ENST00000297405 / NM_001363185.1; = p.V1669= on NM_052900.3) | Silent (SNP) | VAF 93/861 reads (11%) | called by muse, mutect2, varscan2
- CSPG4 | c.2832G>A p.R944= | Silent (SNP) | VAF 9/213 reads (4%) | called by muse, mutect2
- CYP2C19 | c.1212A>T p.P404= | Silent (SNP) | VAF 34/610 reads (6%) | catalogued as COSV64907322; called by muse, mutect2
- DNAH3 | c.9258G>C p.G3086= | Silent (SNP) | VAF 42/373 reads (11%) | called by muse, mutect2, varscan2
- DPPA3 | c.315C>T p.G105= | Silent (SNP) | VAF 54/702 reads (8%) | catalogued as rs746199036; called by muse, mutect2
- FCRL3 | c.672G>C p.L224= | Silent (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- GLDC | c.2163A>G p.G721= | Silent (SNP) | VAF 71/629 reads (11%) | catalogued as rs748569405; called by muse, mutect2, varscan2
- GORASP1 | c.30C>T p.P10= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs1253646412; called by muse, mutect2, varscan2
- GPR149 | c.1158G>A p.A386= | Silent (SNP) | VAF 11/180 reads (6%) | catalogued as COSV67666559; called by muse, mutect2
- INHBB | c.684C>A p.T228= | Silent (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2, varscan2
- KCNT1 | c.873C>A p.V291= (on ENST00000488444; = p.V310= on NM_020822.3) | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- KIAA1549L | c.5394G>A p.A1798= (on ENST00000321505; = p.A2095= on NM_012194.3) | Silent (SNP) | VAF 62/645 reads (10%) | catalogued as rs778857212, COSV58581184; called by muse, mutect2
- KIF26A | c.348C>A p.A116= | Silent (SNP) | VAF 66/830 reads (8%) | called by muse, mutect2
- KRBA1 | c.1683G>T p.A561= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs756099391, COSV55440759; called by muse, mutect2, varscan2
- LRRC66 | c.2031G>T p.L677= | Silent (SNP) | VAF 44/586 reads (8%) | catalogued as COSV100603027; called by muse, mutect2
- MAGEB1 | c.633G>A p.K211= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- MPEG1 | c.1638C>A p.S546= | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as COSV99915926; called by muse, mutect2
- MRPL38 | c.615C>T p.T205= | Silent (SNP) | VAF 28/432 reads (6%) | called by muse, mutect2
- MUC6 | c.2880T>G p.G960= | Silent (SNP) | VAF 15/221 reads (7%) | called by muse, mutect2
- MYBPC2 | c.231G>T p.G77= | Silent (SNP) | VAF 63/268 reads (24%) | called by muse, mutect2, varscan2
- MYH11 | c.5406C>T p.H1802= | Silent (SNP) | VAF 75/758 reads (10%) | catalogued as rs746211825; called by muse, mutect2
- OLFM3 | c.78C>G p.L26= | Silent (SNP) | VAF 47/377 reads (12%) | called by muse, mutect2, varscan2
- OR2G3 | c.273G>T p.T91= | Silent (SNP) | VAF 86/609 reads (14%) | called by muse, mutect2, varscan2
- OR4C5 | c.618A>T p.L206= | Silent (SNP) | VAF 63/813 reads (8%) | called by muse, mutect2
- OR4M2 | c.750G>T p.V250= | Silent (SNP) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- OR56B4 | c.327C>A p.A109= | Silent (SNP) | VAF 28/628 reads (4%) | called by muse, mutect2
- OXCT1 | c.490C>T p.L164= | Silent (SNP) | VAF 327/1294 reads (25%) | called by muse, mutect2, varscan2
- PCDH11X | c.3153G>C p.R1051= | Silent (SNP) | VAF 64/566 reads (11%) | called by muse, mutect2, varscan2
- PCDHB10 | c.2139G>C p.V713= | Silent (SNP) | VAF 43/444 reads (10%) | called by muse, mutect2, varscan2
- PDGFRB | c.129C>A p.V43= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- PHF12 | c.591G>A p.A197= | Silent (SNP) | VAF 37/513 reads (7%) | catalogued as rs541676125, COSV52021078; called by muse, mutect2
- PIK3CA | c.534A>G p.P178= | Silent (SNP) | VAF 46/535 reads (9%) | catalogued as COSV55945302; called by muse, mutect2
- POLQ | c.2586C>T p.I862= | Silent (SNP) | VAF 41/597 reads (7%) | called by muse, mutect2
- POT1 | c.438G>T p.P146= | Silent (SNP) | VAF 44/594 reads (7%) | catalogued as COSV100714087; called by muse, mutect2
- RNASET2 | c.297C>T p.D99= | Silent (SNP) | VAF 96/1044 reads (9%) | catalogued as rs772187999; called by muse, mutect2
- RP1 | c.4962T>C p.S1654= | Silent (SNP) | VAF 82/1194 reads (7%) | called by muse, mutect2
- RYR1 | c.1654C>A p.R552= | Silent (SNP) | VAF 180/860 reads (21%) | catalogued as CM971325, COSV62102500; called by muse, mutect2, varscan2
- RYR1 | c.6687G>A p.V2229= | Silent (SNP) | VAF 54/798 reads (7%) | called by muse, mutect2
- SEMA4C | c.981G>A p.S327= | Silent (SNP) | VAF 30/268 reads (11%) | catalogued as rs914866875, COSV59692253; called by muse, varscan2
- SH3BP5L | c.873C>T p.P291= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs764376654; called by muse, mutect2, varscan2
- SLC22A10 | c.762C>T p.V254= | Silent (SNP) | VAF 29/450 reads (6%) | catalogued as rs1047462912, COSV100235444; called by muse, mutect2
- SNAP91 | c.736C>A p.R246= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as COSV52123632; called by muse, mutect2, varscan2
- SNTA1 | c.255G>A p.R85= | Silent (SNP) | VAF 65/258 reads (25%) | called by muse, mutect2, varscan2
- SPAG11B | c.229C>A p.R77= | Silent (SNP) | VAF 22/620 reads (4%) | called by muse, mutect2
- SSBP1 | c.418C>T p.L140= | Silent (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- TAP1 | c.447C>T p.A149= | Silent (SNP) | VAF 230/1276 reads (18%) | called by muse, varscan2
- TEX15 | c.4950T>G p.A1650= (on ENST00000256246; = p.A2033= on NM_001350162.2) | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- TGFB2 | c.652C>T p.L218= | Silent (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- TMEM37 | c.417C>T p.S139= | Silent (SNP) | VAF 64/690 reads (9%) | catalogued as rs148949485; called by muse, mutect2
- TOGARAM1 | c.1923C>T p.S641= | Silent (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- TRRAP | c.5790G>T p.A1930= (on ENST00000359863 / NM_001244580.1; = p.A1912= on NM_003496.3) | Silent (SNP) | VAF 32/474 reads (7%) | called by muse, mutect2
- UNC13A | c.2223C>A p.R741= | Silent (SNP) | VAF 34/297 reads (11%) | called by muse, mutect2, varscan2
- VWA3A | c.495C>T p.L165= | Silent (SNP) | VAF 58/540 reads (11%) | called by muse, mutect2, varscan2
- VWA3B | c.3273G>T p.P1091= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- ZNF382 | c.1212A>T p.G404= | Silent (SNP) | VAF 76/452 reads (17%) | called by muse, mutect2, varscan2
- ZNF585B | c.900C>T p.C300= | Silent (SNP) | VAF 68/484 reads (14%) | called by muse, varscan2
- ZNF679 | c.717C>G p.P239= | Silent (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
- ABTB1 | c.-30T>G | 5'UTR (SNP) | VAF 40/389 reads (10%) | catalogued as rs1371528601; called by muse, mutect2, varscan2
- AC009053.1 | n.1231T>A | RNA (SNP) | VAF 55/567 reads (10%) | called by muse, mutect2, varscan2
- AC074085.2 | n.305G>T | RNA (SNP) | VAF 62/655 reads (9%) | called by muse, mutect2
- ADI1 | c.420+215G>T | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- AL359195.2 | n.3098C>A | RNA (SNP) | VAF 36/442 reads (8%) | called by muse, mutect2
- ALDH18A1 | c.1468-13C>G | Intron (SNP) | VAF 59/850 reads (7%) | called by muse, mutect2
- B4GALNT4 | c.2870-143A>T | Intron (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- BICDL2 | chr16:3036648 C>A | 5'Flank (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- BLVRA | c.254+17G>T | Intron (SNP) | VAF 70/685 reads (10%) | called by muse, mutect2, varscan2
- CHD5 | c.*68C>A | 3'UTR (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- COL11A1 | c.897+274C>A | Intron (SNP) | VAF 78/572 reads (14%) | called by muse, mutect2, varscan2
- COL22A1 | c.*10G>A | 3'UTR (SNP) | VAF 39/590 reads (7%) | called by muse, mutect2
- CSF2RA | c.*242G>T | 3'UTR (SNP) | VAF 7/78 reads (9%) | catalogued as rs750753313; called by muse, mutect2
- DENND10P1 | n.763T>G | RNA (SNP) | VAF 120/667 reads (18%) | called by muse, mutect2, varscan2
- DGKZ | c.933+51C>G | Intron (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- DMAC2 | c.18+359G>C | Intron (SNP) | VAF 28/330 reads (8%) | called by muse, mutect2
- EP400P1 | n.397G>A | RNA (SNP) | VAF 23/283 reads (8%) | catalogued as rs1410553450; called by muse, mutect2
- F13A1 | c.319+21C>A | Intron (SNP) | VAF 118/799 reads (15%) | called by muse, mutect2, varscan2
- FOXL2NB | c.220+129G>T | Intron (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- GABRG2 | c.1042+12T>C | Intron (SNP) | VAF 50/632 reads (8%) | called by muse, mutect2
- H3P12 | chr3:109410197 G>C | 5'Flank (SNP) | VAF 30/452 reads (7%) | called by muse, mutect2
- IGF2 | c.-4+15G>T | Intron (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- IYD | c.*26G>T | 3'UTR (SNP) | VAF 13/305 reads (4%) | called by muse, mutect2
- KIR3DX1 | n.1169G>T | RNA (SNP) | VAF 142/646 reads (22%) | called by muse, mutect2, varscan2
- KPNA2P3 | n.367A>G | RNA (SNP) | VAF 78/1000 reads (8%) | called by muse, mutect2
- LCN1 | c.*98C>A | 3'UTR (SNP) | VAF 6/112 reads (5%) | catalogued as rs946060201, COSV55017962; called by muse, mutect2
- MT1F | c.-35C>A | 5'UTR (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- NACA | c.70+4733C>T | Intron (SNP) | VAF 38/357 reads (11%) | called by muse, mutect2, varscan2
- NBPF22P | n.1165C>A | RNA (SNP) | VAF 59/572 reads (10%) | catalogued as rs1308201262; called by muse, mutect2, varscan2
- POT1 | c.*1429G>T | 3'UTR (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- PPP2R5C | c.93+23090A>G | Intron (SNP) | VAF 35/290 reads (12%) | catalogued as rs1430058162; called by muse, mutect2, varscan2
- PTGER3 | c.*24-16391C>G | Intron (SNP) | VAF 50/245 reads (20%) | called by muse, mutect2, varscan2
- PTGR1 | chr9:111603884 G>A | 5'Flank (SNP) | VAF 70/717 reads (10%) | called by muse, mutect2
- RAB40C | chr16:630115 A>T | 3'Flank (SNP) | VAF 37/315 reads (12%) | called by muse, mutect2, varscan2
- RCC1 | c.-224G>A | 5'UTR (SNP) | VAF 22/211 reads (10%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20617G>T | Intron (SNP) | VAF 13/317 reads (4%) | catalogued as rs1462760540; called by muse, mutect2
- SP9 | c.-34G>T | 5'UTR (SNP) | VAF 52/288 reads (18%) | called by muse, mutect2, varscan2
- TMEM235 | c.-504G>T | 5'UTR (SNP) | VAF 25/350 reads (7%) | called by muse, mutect2
- UBTFL2 | n.379G>T | RNA (SNP) | VAF 88/1654 reads (5%) | called by muse, mutect2
- VPS8 | c.2454+2245A>T | Intron (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- ZNF48 | chr16:30395399 C>A | 5'Flank (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
